CCDI case PBBLEG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/42c6663f-f0e0-4d94-a211-d29ce9f32c83

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,672 days).

Biospecimens (3 samples)
- Sample 0DBHZ2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBHZ6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBHZC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
